CCDI case PBCAEG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/8e68aac1-c218-482e-9573-f84d1a60195e

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 10.8 years (3,953 days).

Biospecimens (3 samples)
- Sample 0DMBLG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBM0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBM9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
